Somatic mutation profile of tumor specimen TCGA-CN-A49B-01A (aliquot TCGA-CN-A49B-01A-31D-A24D-08) from TCGA case TCGA-CN-A49B, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 71.6 years (26,155 days).
Specimen TCGA-CN-A49B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99fea079-5e76-4b09-8c0b-0de2895168c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A49B-10A (Blood Derived Normal), aliquot TCGA-CN-A49B-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c44e9dbc-037f-4126-9021-6eb7acd36794

The open-access MAF lists 102 somatic variants for this specimen: 73 protein-altering or splice-affecting, 23 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 23, Nonsense Mutation 5, Intron 3, 3'UTR 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 26/47 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCC10 | c.712T>A p.C238S (on ENST00000372530 / NM_001198934.2; = p.C195S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99767047; called by muse, mutect2
- ADAM17 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV60397370; called by muse, mutect2, varscan2
- ADARB1 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.069); catalogued as rs558219105, COSV62341588; called by muse, mutect2, varscan2
- AHNAK2 | c.1814C>A p.A605D | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100316896, COSV100319047; called by muse, mutect2
- ASAP2 | c.558G>C p.E186D | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.358); catalogued as COSV55626592; called by muse, mutect2, varscan2
- ATP1A3 | c.2739G>C p.Q913H (on ENST00000545399 / NM_001256214.2; = p.Q900H on NM_152296.5) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV100132177; called by muse, mutect2
- BCORL1 | c.1288A>G p.M430V | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.661); catalogued as COSV54399662; called by muse, mutect2, varscan2
- CCDC91 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60338693; called by muse, mutect2
- CCNA1 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.072); catalogued as COSV55221599, COSV99714483; called by muse, mutect2
- CETN1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1260493790, COSV59120748; called by muse, mutect2, varscan2
- CNTNAP4 | c.2668C>T p.L890F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV56662504; called by muse, mutect2, varscan2
- COBLL1 | c.1937C>G p.T646S (on ENST00000392717; = p.T608S on NM_014900.5) | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV52062599; called by muse, mutect2, varscan2
- COL5A3 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.865); catalogued as COSV99318555; called by muse, mutect2, varscan2
- COPB2 | c.1682T>C p.M561T | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV60811719; called by muse, mutect2, varscan2
- CSPP1 | c.2674C>T p.P892S (on ENST00000676605; = p.P851S on NM_024790.6) | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV51579689; called by muse, mutect2, varscan2
- DCLK1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs894891178, COSV55169911; called by muse, mutect2, varscan2
- DDX27 | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100873324; called by muse, mutect2, varscan2
- DLAT | c.1222A>C p.T408P | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54768852; called by muse, mutect2, varscan2
- ECHDC1 | c.906A>T p.K302N (on ENST00000531967 / NM_001139510.1; = p.K296N on NM_001002030.2) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV58931179; called by muse, mutect2, varscan2
- EFHC2 | c.220T>A p.F74I | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV69552604, COSV69552621; called by muse, mutect2, varscan2
- EGLN3 | c.42T>G p.I14M | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99164318; called by muse, mutect2, varscan2
- FAM83B | c.1720A>G p.S574G | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV60918912; called by muse, mutect2, varscan2
- FASTKD2 | c.414A>C p.E138D | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV99378903; called by muse, mutect2, varscan2
- FAT2 | c.9014A>T p.N3005I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55812479; called by muse, mutect2
- FBXO33 | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs372862832, COSV53233212; called by muse, mutect2, varscan2
- FMNL1 | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.19); catalogued as rs973119713, COSV100056369; called by muse, mutect2, varscan2
- FNDC1 | c.5051G>A p.G1684E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51929864; called by muse, varscan2
- FRS2 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 298/1192 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs112443855, COSV54722796; called by muse, mutect2, varscan2
- GEN1 | c.1912A>G p.R638G | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV58055101; called by muse, mutect2, varscan2
- H2AC12 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63616978, COSV99052675; called by muse, mutect2
- HNRNPA3 | c.1127G>A p.R376K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); catalogued as COSV101182889; called by muse, mutect2, varscan2
- HSD17B6 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs771218376, COSV59107082; called by muse, mutect2, varscan2
- IGHM | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); catalogued as rs782792312; called by muse, mutect2, varscan2
- IKZF4 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs748239833, COSV100008999; called by muse, mutect2, varscan2
- IRF6 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV65418603, COSV65418619; called by muse, mutect2, varscan2
- JADE2 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs749616438, COSV50911490; called by muse, mutect2, varscan2
- KCNH5 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59751878, COSV59753058; called by muse, mutect2, varscan2
- KCNT2 | c.1591A>G p.N531D | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs778676289, COSV54062284; called by muse, mutect2, varscan2
- KIF1C | c.1929G>T p.M643I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100297058, COSV57904386; called by muse, mutect2
- KRIT1 | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 66/375 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56058209; called by muse, mutect2, varscan2
- LAMA3 | c.6794A>G p.N2265S (on ENST00000313654 / NM_198129.4; = p.N656S on NM_000227.6) | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV52529050; called by muse, mutect2, varscan2
- MPP7 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV61729677, COSV61738112; called by muse, mutect2, varscan2
- MSL1 | c.1135C>T p.R379C (on ENST00000398532 / NM_001365919.1; = p.R116C on NM_001012241.2) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as COSV100278081; called by muse, mutect2, varscan2
- MYH13 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV99353393; called by muse, mutect2, varscan2
- MYO5B | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.227); catalogued as rs754688861, COSV53210211; called by muse, mutect2, varscan2
- NAGS | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs771540094, CM167134, COSV99243765; called by muse, mutect2, varscan2
- NYAP1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.295); catalogued as rs1039037946, COSV100278439; called by muse, mutect2
- OR5J2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.662); catalogued as COSV100398972; called by muse, mutect2
- PCDHGC4 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99339358; called by muse, mutect2, varscan2
- PLAG1 | c.1046A>G p.E349G | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV57608895; called by muse, mutect2, varscan2
- PLEKHH3 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 8/97 reads (8%) | catalogued as COSV99257477; called by muse, mutect2
- PPP1R32 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770730184, COSV100087767; called by muse, mutect2, varscan2
- PRKDC | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV100039763; called by muse, mutect2
- PTDSS2 | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781072653, COSV57276843; called by muse, mutect2, varscan2
- RAX | c.387G>C p.E129D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.121); catalogued as COSV56873860; called by muse, mutect2, varscan2
- RCAN3 | c.477G>C p.Q159H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV65558063; called by muse, mutect2, varscan2
- RFX2 | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100353672, COSV99051849; called by muse, mutect2, varscan2
- RPS6KA1 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); catalogued as COSV100943021; called by muse, mutect2
- SCAP | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs540829159, COSV55558578; called by muse, mutect2, varscan2
- SF1 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 32/133 reads (24%) | catalogued as rs1167826578, COSV57110916; called by muse, mutect2, varscan2
- SOWAHB | c.1664A>T p.K555M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100530666; called by muse, mutect2, varscan2
- SPEN | c.5843C>T p.P1948L | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65366030; called by muse, mutect2, varscan2
- STPG1 | c.469G>T p.V157F (on ENST00000337248 / NM_001199013.2; = p.V110F on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV50217544; called by muse, mutect2, varscan2
- TASOR2 | c.5632G>C p.E1878Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV60165183; called by muse, mutect2, varscan2
- TRAPPC9 | c.2914G>T p.E972* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV66892388; called by muse, mutect2, varscan2
- TTI1 | c.2279T>A p.L760Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65060296; called by muse, mutect2, varscan2
- UBE2R2 | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV54287448; called by muse, mutect2, varscan2
- ZFHX3 | c.4732C>G p.Q1578E | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV99196674; called by muse, mutect2, varscan2
- ZMYM6 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as rs759676745, COSV58183456; called by muse, mutect2, varscan2
- ZNF521 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.838); catalogued as rs774175248, COSV64121536; called by muse, mutect2, varscan2
- ZNF584 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.033); catalogued as COSV100183256, COSV100183395; called by muse, mutect2, varscan2
- IL20RB | c.426del p.M143Wfs*41 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | called by mutect2, pindel, varscan2
- ARHGEF15 | c.729G>A p.P243= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as rs773448584, COSV62724211; called by muse, mutect2, varscan2
- CDCA8 | c.159C>T p.L53= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs142159015; called by muse, mutect2, varscan2
- CHTF18 | c.1878C>T p.T626= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs1278500094; called by muse, mutect2
- DHTKD1 | c.2415C>T p.L805= | Silent (SNP) | VAF 66/227 reads (29%) | catalogued as rs1460366028, COSV53801438; called by muse, mutect2, varscan2
- LTV1 | c.423C>T p.D141= | Silent (SNP) | VAF 11/302 reads (4%) | catalogued as COSV62536132; called by muse, mutect2
- MICALL1 | c.2583C>T p.D861= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99317170; called by muse, mutect2, varscan2
- MINDY4 | c.1488C>T p.V496= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV54670898; called by muse, mutect2, varscan2
- MMP10 | c.247C>T p.L83= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as COSV54245291; called by muse, mutect2, varscan2
- NLRP10 | c.1260G>T p.G420= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100149607; called by muse, mutect2, varscan2
- OR52E4 | c.564G>A p.G188= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as rs1246289004, COSV57623689; called by muse, mutect2, varscan2
- PAPPA2 | c.2986C>T p.L996= | Silent (SNP) | VAF 81/230 reads (35%) | catalogued as COSV62789942; called by muse, mutect2, varscan2
- PEX26 | c.894C>G p.L298= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV100299063; called by muse, varscan2
- PML | c.327C>T p.F109= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs1185807473, COSV51455588; called by muse, mutect2, varscan2
- RSF1 | c.1797C>T p.D599= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as rs762997932, COSV57837049; called by muse, mutect2, varscan2
- RUVBL2 | c.546G>C p.L182= | Silent (SNP) | VAF 9/124 reads (7%) | catalogued as COSV99668940; called by muse, mutect2
- SEPTIN11 | c.756C>A p.A252= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV53580153; called by muse, mutect2
- TBC1D9 | c.1290C>T p.L430= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs372798452; called by mutect2, varscan2
- THEG | c.150G>A p.L50= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV61072803; called by muse, mutect2, varscan2
- TULP4 | c.3465G>A p.L1155= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs746726576, COSV65571636, COSV65580519; called by muse, mutect2, varscan2
- XIRP1 | c.711G>A p.T237= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs141262169, COSV100453528; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1932C>T p.F644= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV56271521; called by muse, mutect2, varscan2
- ZNF566 | c.111G>A p.E37= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV101091346; called by muse, mutect2
- ZNF831 | c.3024C>T p.P1008= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100925952; called by muse, mutect2, varscan2
- ACSM1 | c.1197+217A>T | Intron (SNP) | VAF 38/85 reads (45%) | catalogued as COSV99532803; called by muse, mutect2, varscan2
- CTAG2 | c.*73G>A | 3'UTR (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99908741, COSV99908877; called by muse, mutect2, varscan2
- MARCHF5 | c.*2A>T | 3'UTR (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100739586, COSV62768964; called by muse, mutect2, varscan2
- MIR518B | n.42G>A | RNA (SNP) | VAF 15/40 reads (38%) | catalogued as rs1302766538; called by muse, mutect2, varscan2
- TTN | c.10361-4646G>C | Intron (SNP) | VAF 21/73 reads (29%) | catalogued as COSV59866620, COSV60090308; called by muse, mutect2, varscan2
- WNK1 | c.1312-5445T>A | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100266974; called by muse, mutect2, varscan2
